Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3430, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3430-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):

- A: Cartilage from 11th rib
- B: Lymph Node, para aortic
- C: Renal cyst wall
- D: Left peri renal fat
- E: Left kidney and adrenal
- F: Lymph Node, para aortic

Gross Description:

Received in six parts.

Source of Tissue: 1. Labeled #1, "cartilage from 11th rib"

Gross Description: Received fresh is a 3.0 x 1.0 cm tan firm fragment of rib. A representative section is submitted in one block, following decalcification.

Designation of Sections: Block 1

Summary of Sections: undesignated-1

Source of Tissue: 2. Labeled #2, "para aortic lymph node"

Frozen Section Diagnosis: 2FS- CLEAR CELL

Gross Description: Received fresh for frozen section evaluation is a 2.0 cm in greatest dimension tan firm lymph node with attached adipose tissue. It is sectioned to reveal yellow to golden-orange firm cut surfaces. A representative section is submitted for frozen section evaluation and the frozen section residue is submitted in one block. Additional representative sections are submitted in one block.

Designation of Sections: 2FS, 2

Summary of Sections: multiple

Source of Tissue: 3. Labeled #3, "renal cyst wall"

Frozen Section Diagnosis: 3FS- BENIGN CYST PER

Gross Description: Received fresh for frozen section evaluation is a 3.0 x 1.0 x 0.3 cm tan membranous fragment of soft tissue with attached adipose tissue. The cyst wall is entirely submitted for frozen section evaluation and the frozen section residue is submitted in one block. The remaining

[page 2 of 3]
adipose tissue is entirely submitted in one block.

Designation of Sections: 3FS, 3

Summary of Sections: multiple

Source of Tissue: 4. Labeled #4, "left perirenal fat"

Gross Description: Received fresh are 133 grams of yellow-tan perirenal fat. The fragments are sectioned to reveal yellow-tan lobulated glistening cut surfaces. Representative sections are submitted in three blocks.

Designation of Sections: 4A-4C

Summary of Sections: multiple

Source of Tissue: 5. Labeled #5, "left kidney and adrenal"

Gross Description: Received fresh is a 606 gram left nephrectomy with attached adrenal gland and a moderate amount of attached perinephric fat. There is a 9.0 x 0.2 cm fragment of attached ureter having a lumen, 0.2 cm in greatest dimension which is probe patent to the renal hilum. The kidney itself is 11.5 x 6.0 x 6.0 cm in greatest dimension being covered by a red-purple capsule. It is bivalved to reveal red-purple firm renal parenchyma having a well-defined cortico-medullary junction. In the upper pole there is a 6.5 x 5.5 x 5.0 cm mass having tan to golden-yellow-orange nodular variegated cut surfaces with irregular borders. Adjacent to this mass, on the capsular surface is a 4.0 cm in greatest dimension depressed area consistent with the previous frozen section (3FS, renal cyst). This area is inked in blue and the remaining margins are inked in black. There is a 4.5 x 2.0 x 0.3 cm attached adrenal gland having golden-yellow-orange unremarkable cut surfaces. Representative sections are submitted in ten blocks.

Designation of Sections: 5A- ureter and vascular margins, 5B-5F- upper pole mass, 5G-5H- sections from area of previous frozen section (3FS), 5I- random section kidney, 5J- adrenal gland

Summary of Sections: multiple

Source of Tissue: 6. Labeled #6, "para aortic lymph nodes"

Gross Description: Received fresh are 6.5 x 3.5 x 2.5 cm of yellow-tan fibroadipose tissue. There are multiple palpable lymph nodes, 0.6 to 1.2 cm in greatest dimension. The lymph nodes are entirely submitted in six blocks.

[page 3 of 3]
Designation of Sections: 6A-6F, each block has one lymph node

Summary of Sections: multiple

Final Diagnosis:

1. Portion of 11th rib (excision):
- No tumor seen.
2. Lymph node, para aortic (excision):
- Positive for metastatic carcinoma (1/1).
3. Left renal cyst (excision):
- Benign cyst.
4. Left perirenal fat (excision):
- No tumor seen.
5. Left kidney and adrenal (left radical nephrectomy):
- Renal cell adenocarcinoma, clear cell type (6.5 cm), nuclear grade 2-3 arising in upper pole and invading into renal sinus.
- Vein invasion is identified.
- The ureter, vascular and circumferential margins of resection are free of tumor.
- Negative adrenal gland.
6. Lymph nodes, para aortic (excision):
- Metastatic carcinoma (2/7).

Source: NCI Genomic Data Commons file 76f2e955-3e69-4215-b862-c3f60be2d82c (TCGA-AK-3430.F805BEA6-9A63-40BA-9101-424CC99FD53A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).